Gene-level copy-number profile of tumor specimen TCGA-NH-A6GA-01A from TCGA case TCGA-NH-A6GA, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 58.4 years (21,313 days).
Specimen TCGA-NH-A6GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.144eba77-c4ad-4835-be28-72722376eded.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NH-A6GA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-NH-A6GA-01A|TCGA-NH-A6GA-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09fdac96-4025-404e-9460-c3e80df4cce5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,104; copy number 2: 37,191; copy number 3: 6,521; copy number 4: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NH-A6GA-01A-11D-A36W-01): tumor purity 0.8, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,683. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
